Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A61B, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A61B-01A (Primary Tumor).

ICD-O-3
Astrocytoma, anaplastic
9401/3
Site: Supratentorial NOS
071.0
gnw 4/16/13

Pathology report for

Discussion:

Numerous MIB-1 reactive cells are present throughout the tumor. In the most proliferative areas, a labeling index of 22.9% is calculated.

Diagnosis:

Anaplastic astrocytoma (grade III)

- MIB-1 LI - 22.9%

Source: NCI Genomic Data Commons file 82ed2f13-b89d-4413-ad2d-d09157c1684b (TCGA-HT-A61B.24042BE1-BDC3-41A3-93EE-872D5E3B99F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).